Surgical pathology report (de-identified scan), TCGA case TCGA-33-4547, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4547-01A (Primary Tumor).

[page 1 of 5]
INTERPRETATION AND DIAGNOSIS:

1) R11 (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE
TISSUE, NEGATIVE FOR TUMOR.

2) RIGHT UPPER LOBE (LOBECTOMY):

SPECIMEN TYPE:

Lobectomy

TUMOR SITE:

Right upper lobe

HISTOLOGIC TYPE:

Non-small cell carcinoma with squamous features

TUMOR SIZE:

4.5 cm greatest dimension

HISTOLOGIC GRADE:

G3: Poorly differentiated

LYMPH NODES:

All 13 lymph nodes are negative for tumor

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor which is >3 cm

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins uninvolved by invasive carcinoma

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

Absent

(Continued on next page.)

[page 2 of 5]
LYMPHATIC (SMALL VESSEL) INVASION:
Indeterminate

3) R10 (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE
TISSUE, NEGATIVE FOR TUMOR.

4) R4 (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE
TISSUE, NEGATIVE FOR TUMOR.

5) HIGH R4 (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE
TISSUE, NEGATIVE FOR TUMOR.

6) STATION 7 (EXCISION): FIVE (5) LYMPH NODES AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Note: This case was shown at the daily quality assurance conference.

[REDACTED]

*Electronic signature
=====

Clinical History:
NOT PROVIDED

GROSS DESCRIPTION

PART #1: R11 (clg)

Resident Pathologist: [REDACTED]

[REDACTED] [REDACTED] [REDACTED] [REDACTED]

The specimen is received fresh labeled with the patient's name, .
and is designated R11. The specimen consists of one piece of
red-tan-black soft tissue measuring 1.5 x 1.0 x 0.8 cm. One half the
specimen is submitted. The other half has been procured for research.

SUMMARY OF SECTIONS

1 - A - 1

1 - TOTAL - 1

(Continued on next page.)

[page 3 of 5]
PART #2: RT UPPER LOBE
Resident Pathologist:

The specimen is received fresh labeled with the patient's name, and is designated right upper lobe. The specimen consists of a lobectomy specimen weighing 180.0 gm and measuring 15.0 x 12.0 x 5.5 cm. There is an extensive area of pleural puckering measuring approximately 4.0 cm in greatest dimension located in the lateral aspect of this specimen. The pleura overlying the puckering is inked in black and the specimen is sectioned. Upon sectioning, there is a tan-white-yellowish mass that is adjacent to the pleura measuring 4.5 x 4.0 x 4.0 cm. A portion of the specimen has been procured. Representative sections of the specimen and the margin are submitted. The tumor is located approximately 2.5 cm from the bronchial margin and approximately 2.0 cm from the stapled margin. Representative sections of the specimen are submitted.

SUMMARY OF SECTIONS

1 - A - MULTIPLE (VASCULAR MARGINS)
1 - B - 2 (BRONCHIAL MARGIN)
1 - C - 1 (NORMAL LUNG)
7 - D-J - 1 EACH (TUMOR)
10 - TOTAL - M

PART #3: R10 (clg)
Resident Pathologist:

The specimen is received fresh labeled with the patient's name, and is designated R10. The specimen consists of one piece of red-tan-black soft tissue measuring 0.8 x 0.5 x 0.5 cm. One half of the specimen is submitted.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

(Continued on next page.)

[page 4 of 5]
=====

PART #4: R4 [REDACTED]

[REDACTED]: [REDACTED]

The specimen is received fresh labeled with the patient's name, and is designated low R4. The specimen consists of one piece of red-tan-pink soft tissue measuring 2.0 x 1.5 x 0.8 cm. One half of the specimen is submitted.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #5: HIGH R4 (clg)
Resident Pathologist: [REDACTED]

The specimen is received fresh labeled with the patient's name, and is designated as high R4. The specimen consists of one piece of red-tan-pink soft tissue measuring 1.0 x 0.9 x 0.6 cm. One half of the specimen is submitted.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

(Continued on next page.)

[page 5 of 5]
=====

PART #6: STATION 7 [REDACTED]
Resident Pathologist: [REDACTED]

The specimen is received fresh labeled with patient's name, [REDACTED] and is designated station 7. The specimen consists of one piece red-tan-yellow-black soft tissue measuring 1.5 x 1.0 x 0.6 cm. Four possible lymph nodes are identified, the largest possible lymph node measures 0.9 x 0.3 x 0.2 cm. 90% of the specimen is submitted.

SUMMARY OF SECTIONS

- 1 - A - 1 (LARGE POSSIBLE LYMPH NODE)
- 1 - B - 1 (ONE HALF OF POSSIBLE LYMPH NODE)
- 1 - C - 2 (2 POSSIBLE LYMPH NODES)
- 1 - D - MULTIPLE (REMAINING FAT)
- 4 - TOTAL - M

=====

(End of Report) [REDACTED]

Source: NCI Genomic Data Commons file 3dc2bd30-518b-447e-99bd-9d8533865518 (TCGA-33-4547.C2A8E692-5B5A-4A56-85E9-165E523A341C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).